Somatic mutation profile of tumor specimen TARGET-10-PAPSPG-03A (aliquot TARGET-10-PAPSPG-03A-01D) from TARGET case TARGET-10-PAPSPG, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.1 years (4,782 days).
Specimen TARGET-10-PAPSPG-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34a78967-7383-43ba-8266-6c439ce25d33.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPSPG-10A (Blood Derived Normal), aliquot TARGET-10-PAPSPG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc520ad1-4f77-466e-b67b-9df57486a8b6

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Nonsense Mutation 3, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GABRR1 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 82/208 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781685308, COSV65618863; called by muse, mutect2, varscan2
- ORM1 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 136/764 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs745748857, COSV52278438; called by muse, mutect2, varscan2
- PCDHB4 | c.1228C>T p.R410* | Nonsense Mutation (SNP) | VAF 39/146 reads (27%) | catalogued as COSV52020017; called by muse, mutect2, varscan2
- TTC30A | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 39/83 reads (47%) | catalogued as COSV63100532; called by muse, mutect2, varscan2
- VIT | c.1060C>T p.R354* (on ENST00000389975 / NM_001177969.1; = p.R369* on NM_053276.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 159/354 reads (45%) | catalogued as rs377073906, COSV64895453, COSV64896966; called by muse, mutect2, varscan2
- ADGRB3 | c.633G>A p.S211= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs144107434; called by muse, mutect2, varscan2
- ARFGEF3 | c.5802C>T p.G1934= | Silent (SNP) | VAF 24/45 reads (53%) | catalogued as rs1317856418, COSV52451277; called by muse, mutect2, varscan2
- PARP15 | c.498T>C p.H166= | Silent (SNP) | VAF 68/151 reads (45%) | catalogued as COSV59971537; called by muse, mutect2, varscan2
- PCYT2 | c.1074G>A p.A358= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as rs200834115; called by muse, mutect2, varscan2
